Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A18A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A18A-01A (Primary Tumor).

adenocarcinoma, endometrioid, NOS 8380/3

Site Code: Endometrium C54.1

lw
10/27/14**PATIENT HISTORY:**

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.

LMP DATE: Postmenopausal.

PROCEDURE: Laparoscopic TAH, BSO, pelvic lymph node dissection, cystoscopy.

SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: Not provided.

PRIOR MALIGNANCY: Not provided.

CHEMORADIATION THERAPY: Not provided.

OTHER DISEASES: Not provided.

**FINAL DIAGNOSIS:**

PART 1: LYMPH NODES, LEFT PELVIC, DISSECTION -

SEVEN LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/7).

PART 2: LYMPH NODES, LEFT COMMON, DISSECTION -

TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 3: LYMPH NODES, RIGHT PELVIC, DISSECTION -

FOUR LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/4).

PART 4: LYMPH NODES, RIGHT COMMON, DISSECTION -

A. BENIGN FIBROADIPOSE TISSUE.

B. NO LYMPHOID TISSUE SEEN.

Need 2 of
mucinous features
must be $\leq 9\%$
yes 12/24/14 = 1.5%
lw

PART 5: UTERUS, CERVIX, BILATERAL ADNEXA, LAPAROSCOPIC TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY -

A. WELL-DIFFERENTIATED ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE, FIGO GRADE 1, WITH FOCAL MUCINOUS FEATURES.

B. TUMOR SIZE IS 3.5 CM.

C. TUMOR INVOLVES GREATER THAN 90% OF ANTERIOR AND POSTERIOR ENDOMETRIAL CAVITY.

D. TUMOR INVADERS LESS THAN 50% OF THE MYOMETRIAL THICKNESS.

E. NO LYMPHOVASCULAR SPACE INVASION IS SEEN.

F. LEIOMYOMA, 1.4 CM.

G. FOCAL ENDOSALPINGIOSIS INVOLVING UTERINE SEROSA.

H. CERVIX, NEGATIVE FOR TUMOR.

I. OVARIES AND FALLOPIAN TUBES, BILATERAL, NEGATIVE FOR TUMOR.

COMMENT:

Companion pelvic wash cytology specimen

negative for malignant cells. Tumor is FIGO stage IA.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Well differentiated (FIGO 1)

TUMOR SIZE: Maximum dimension: 35 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 90 %, Posterior endomyometrium: 90 %

DEPTH OF INVASION: Less than 1/2 thickness of myometrium

ANGIOLYMPHATIC INVASION: No

LYMPH NODES POSITIVE: Number of lymph nodes positive: 0

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 13

T STAGE, PATHOLOGIC: pT1a

N STAGE, PATHOLOGIC: pN0

M STAGE, PATHOLOGIC: Not applicable

FIGO STAGE: IA

Diagnosis Discrepancy		K
Primary Tumor Site Discrepancy		K
H/PA Discrepancy		K
Prior Malignancy History		K
Dual/Synchronous Primary Nodes		K

Source: NCI Genomic Data Commons file 54accebb-e69a-4287-ae6d-7c3e9d360b08 (TCGA-BG-A18A.099561AC-A5E7-4CA9-8F07-EEA7B3A96EEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).